Surgical pathology report (de-identified scan), TCGA case TCGA-LK-A4NZ, project TCGA-MESO (Mesothelioma), tissue source site University of Pittsburgh, specimen TCGA-LK-A4NZ-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: LUNG, RIGHT LOWER LOBE, BIOPSY -
BENIGN BRONCHIAL MUCOSA.

PART 2: BONE, THIRD RIB, RESECTION-

- A. SOFT TISSUE WITH A DIFFUSE MALIGNANT MESOTHELIOMA, EPITHELIOID TYPE.
- B. UNREMARKABLE BONE AND BONE MARROW.

PARTS 3

AND 4: PLERA, RIGHT, RESECTION -

- A. DIFFUSE MALIGNANT MESOTHELIOMA, EPITHELIOID TYPE, EXTENDING INTO ADJACENT LUNG PARENCHYMA (see comment).
- B. PLEURAL HYALINE PLAQUE.

COMMENT:

The histomorphology of the tumor shows a diffuse malignant mesothelioma with a predominantly epithelioid variant. However, a tubulopapillary pattern is focally seen.

Addendum

Probe: Dual Color Probe

RESULTS :

Fluorescence in situ hybridization studies performed on the malignant mesothelioma demonstrate 1 (1.6%) cells with homozygous loss and 10 (15.6%) of cells with hemizygous loss. The ratio of *p16* (9p21) to the centromere of chromosome 9 was 0.95. The targeted region (total 64 cells) is considered to be NEGATIVE for *p16* (9p21) deletion.

Interpretation guidelines for 9p21 by FISH:

Ratio of *p16* to the centromere of chromosome 9:

Normal Range Ratio: 0.85-1.19

Normal % deletion: less than 20%

Clinical studies indicate diagnostic and prognostic significance of *p16* deletion in malignant mesotheliomas.

FISH analysis was manually performed and quantitatively assessed by analysis of a minimum of 60 cells.

Reference:

Illei P, Ladanyi M, Rusch V, Zakowski M. *The Use of CDKN2A Deletion as a Diagnostic Marker for Malignant Mesothelioma in Body Cavity Effusions.* Cancer (Cancer Cytopathology), 99(1):Feb 25, 2003.

Lopez-Rios F, Ladanyi M, et al. *Global Gene Expression Profiling of Pleural Mesotheliomas: Overexpression of Aurora Kinases and P16/CDKN2A Deletion as Prognostic Factors and Critical Evaluation of Microarray-Based Prognostic Prediction.* Cancer Res 2006; 66 (8): March 15, 2006.

Chiose S, Krasinskas A, Cagle PT, Mitchell KA, Zander DS, Dacic S. *Diagnostic Importance of 9p21 homozygous deletion in malignant mesotheliomas.* Mod Pathol. 2008 Jun;21(6):742-7.

1CB-0-3

Mesothelioma, epithelioid, NOS 9052/3

Site: pleura, NOS C38.4

hw
7/25/12

Inter-Malignancy History		☒

Source: NCI Genomic Data Commons file 28a422d4-d62a-4a1c-9d33-6ec975080688 (TCGA-LK-A4NZ.ABE9C586-6C72-42F3-8007-22762DA9C7A9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).